Somatic mutation profile of tumor specimen TCGA-21-1076-01A (aliquot TCGA-21-1076-01A-02D-1521-08) from TCGA case TCGA-21-1076, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.4 years (19,863 days).
Specimen TCGA-21-1076-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 977b5851-0948-4180-b520-2a377d2a1aa6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1076-11A (Solid Tissue Normal), aliquot TCGA-21-1076-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99bc9ab4-b90f-4ac9-ab67-7d5165b6b798

The open-access MAF lists 329 somatic variants for this specimen: 254 protein-altering or splice-affecting, 69 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 215, Silent 69, Nonsense Mutation 18, Splice Site 10, Frame Shift Del 7, RNA 4, Splice Region 2, 3'UTR 2, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OTC | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.778); catalogued as rs72554338, CM920534, COSV50003137; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 36/132 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV56644794; called by muse, mutect2, varscan2
- ADAM2 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV55862796; called by muse, mutect2
- ADAMTS12 | c.1037C>A p.T346N | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61262000; called by muse, mutect2, varscan2
- ADAMTS16 | c.1119G>A p.M373I | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV56998405; called by muse, mutect2, varscan2
- ADGRE1 | c.2405C>A p.A802D | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV51678438; called by muse, mutect2, varscan2
- ADGRV1 | c.4505C>T p.P1502L | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67979234, COSV67990460; called by muse, mutect2, varscan2
- ADNP2 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs780534183, COSV51540836; called by muse, mutect2, varscan2
- AKAP14 | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV57630739; called by muse, mutect2
- AKAP4 | c.2458G>T p.G820C | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV62074928; called by muse, mutect2, varscan2
- AMBP | c.451T>C p.Y151H | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54324679; called by muse, mutect2
- APEX2 | c.1386del p.L464Cfs*14 | Frame Shift Del (DEL) | VAF 9/90 reads (10%) | catalogued as COSV100237847; called by mutect2, pindel, varscan2
- ARHGEF28 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV55263223; called by muse, mutect2, varscan2
- ARHGEF9 | c.5C>A p.T2K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.972); catalogued as COSV53641071; called by muse, mutect2, varscan2
- ASXL1 | c.3343A>G p.S1115G | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV60114370; called by muse, mutect2, varscan2
- ATG7 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753893278, COSV61611102; called by muse, varscan2
- BCAN | c.590T>A p.L197H | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.194); catalogued as COSV61258135; called by muse, mutect2, varscan2
- BCHE | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52259515; called by muse, mutect2, varscan2
- BTK | c.1349+1G>T p.X450_splice | Splice Site (SNP) | VAF 36/257 reads (14%) | catalogued as CS022091, CS971634, COSV58122059; called by muse, mutect2, varscan2
- C14orf39 | c.1501C>A p.Q501K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV58783568; called by muse, varscan2
- C1orf159 | c.420G>T p.G140= (on ENST00000379339 / NM_001330306.2; = p.G104= on NM_017891.5) | Splice Region (SNP) | VAF 7/45 reads (16%) | catalogued as COSV53882094; called by muse, mutect2, varscan2
- CACNA1H | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.257); catalogued as rs766768686, COSV61988218; called by muse, mutect2
- CACYBP | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV100871610, COSV62881371; called by muse, mutect2, varscan2
- CASS4 | c.1571C>A p.S524Y | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV64387438; called by muse, mutect2, varscan2
- CCDC144A | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV60700047; called by muse, mutect2, varscan2
- CCDC22 | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as COSV100873161; called by muse, mutect2, varscan2
- CCSER1 | c.1865G>T p.R622I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1053213704, COSV61449106; called by muse, mutect2, varscan2
- CD300E | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60791097; called by muse, mutect2
- CEACAM20 | c.85G>C p.A29P | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV57602472; called by muse, mutect2, varscan2
- CHD5 | c.2822C>A p.P941Q | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52418325; called by muse, mutect2
- CHRNA5 | c.294G>T p.W98C | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55139501; called by muse, mutect2, varscan2
- CILP | c.3476G>A p.S1159N | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs776934891, COSV56026142; called by muse, mutect2, varscan2
- CMIP | c.1709G>A p.G570D (on ENST00000537098 / NM_198390.2; = p.G476D on NM_030629.3) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV67699492; called by muse, mutect2, varscan2
- CORO2A | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs773618810, COSV59663934; called by muse, mutect2, varscan2
- CPS1 | c.602T>A p.I201N | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV51817268; called by muse, mutect2
- CR1 | c.5362A>G p.T1788A | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV65460450; called by muse, mutect2
- CRABP1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as rs1265380738, COSV55116080; called by muse, mutect2, varscan2
- CRNKL1 | c.290A>T p.Q97L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55638433; called by muse, mutect2, varscan2
- CRYZ | c.630+1G>T p.X210_splice | Splice Site (SNP) | VAF 3/36 reads (8%) | catalogued as COSV61717647, COSV61718223; called by muse, mutect2
- CSMD2 | c.877A>T p.N293Y | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV53935059; called by muse, mutect2, varscan2
- CYBB | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV66085880; called by muse, mutect2, varscan2
- DBF4 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55997946; called by muse, mutect2, varscan2
- DEFB116 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV68722309; called by muse, mutect2
- DGKD | c.2403T>A p.Y801* (on ENST00000264057 / NM_152879.3; = p.Y757* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/110 reads (16%) | catalogued as COSV51070943; called by muse, mutect2, varscan2
- DNAH5 | c.2936A>T p.E979V | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV54239503; called by muse, mutect2, varscan2
- DNAH9 | c.7345G>T p.A2449S | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.122); catalogued as COSV52362377; called by muse, mutect2, varscan2
- DOCK9 | c.1418T>A p.F473Y (on ENST00000376460 / NM_001366676.2; = p.F474Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.075); catalogued as COSV59636457; called by muse, mutect2
- DPCD | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64509667; called by muse, mutect2, varscan2
- DPPA5 | c.67C>G p.P23A | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV64875809; called by muse, mutect2
- DPYSL4 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs748333066, COSV58307708, COSV58308721; called by muse, mutect2, varscan2
- DTNA | c.1343C>A p.S448Y | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV52014921; called by muse, mutect2
- DYNC2I1 | c.3044G>C p.G1015A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV68104809, COSV68105982; called by muse, mutect2, varscan2
- EBF1 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 31/164 reads (19%) | catalogued as COSV58187120; called by muse, mutect2, varscan2
- ECM2 | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV60742008; called by muse, mutect2, varscan2
- EFCAB7 | c.937C>G p.Q313E | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.095); catalogued as COSV60683519; called by muse, mutect2
- ENAM | c.2608C>T p.Q870* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV68536568; called by muse, mutect2, varscan2
- ENPP4 | c.1144C>G p.P382A | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV58089571; called by muse, mutect2
- ENTHD1 | c.1077G>T p.Q359H | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57322658, COSV57323545; called by muse, mutect2, varscan2
- EP400 | c.4042G>C p.V1348L | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV57779077; called by muse, mutect2, varscan2
- EPPIN-WFDC6 | c.417A>T p.E139D | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV60549128; called by muse, mutect2, varscan2
- ERCC6L | c.2664G>T p.E888D | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV57819598; called by muse, mutect2
- EYA4 | c.990A>T p.G330= (on ENST00000531901 / NM_001301013.1; = p.G324= on NM_004100.5) | Splice Region (SNP) | VAF 20/153 reads (13%) | catalogued as COSV62057109; called by muse, mutect2, varscan2
- EYS | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as COSV60982434; called by muse, mutect2, varscan2
- EZH2 | c.1120G>C p.E374Q (on ENST00000460911 / NM_001203247.2; = p.E379Q on NM_004456.5) | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.493); catalogued as rs144316514, COSV57451430; called by muse, mutect2
- FAM199X | c.843C>A p.S281R | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV55434124; called by muse, mutect2
- FCN1 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.223); catalogued as COSV65662673; called by muse, mutect2, varscan2
- FGD3 | c.2119G>T p.A707S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV61598831; called by muse, mutect2, varscan2
- FRMPD4 | c.3436C>G p.Q1146E | Missense Mutation (SNP) | VAF 42/422 reads (10%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.137); catalogued as COSV66219225; called by muse, mutect2
- FSHR | c.1482G>C p.W494C | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58628920; called by muse, mutect2, varscan2
- GABRR2 | c.926C>A p.T309K | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV68764262, COSV68765679; called by muse, mutect2, varscan2
- GBX1 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1267465497, COSV52548208, COSV52549208; called by muse, mutect2
- GLRA2 | c.176A>T p.D59V | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54344392, COSV99490558; called by muse, mutect2
- GOLGA4 | c.2372G>T p.G791V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV62712157; called by muse, mutect2, varscan2
- GOLGB1 | c.5318T>C p.L1773P | Missense Mutation (SNP) | VAF 48/385 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV61468219; called by muse, mutect2, varscan2
- GPR12 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1368851574; called by muse, mutect2
- GRB10 | c.1512C>A p.H504Q (on ENST00000398812; = p.H458Q on NM_001001549.3) | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as COSV60013200; called by muse, mutect2
- GRM3 | c.954C>A p.Y318* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV64468447, COSV64475846; called by muse, mutect2, varscan2
- GUCY1A1 | c.839C>G p.S280W | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56649234, COSV56653780; called by muse, mutect2, varscan2
- HACE1 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53504811; called by muse, varscan2
- HCN4 | c.1217A>T p.H406L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56085499; called by muse, mutect2, varscan2
- HEATR5A | c.1574G>A p.G525E | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66343500; called by muse, mutect2, varscan2
- HEATR6 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV51747288; called by muse, mutect2, varscan2
- HELZ | c.2475G>T p.Q825H | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62379681; called by muse, mutect2, varscan2
- HIRA | c.494-2A>G p.X165_splice | Splice Site (SNP) | VAF 9/61 reads (15%) | catalogued as COSV54277309; called by muse, mutect2, varscan2
- HOXD1 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.067); catalogued as rs753497224; called by muse, mutect2
- HSD3B1 | c.1051C>A p.Q351K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV52491476; called by muse, mutect2, varscan2
- HTATSF1 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV54479973; called by muse, mutect2, varscan2
- ICAM3 | c.1592C>A p.T531K | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs372536524; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.217A>G p.S73G | Missense Mutation (SNP) | VAF 17/364 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs777590073; called by muse, mutect2
- IGKV2D-29 | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs1241311912, COSV101534394; called by mutect2, varscan2
- IL13RA2 | c.1139C>G p.T380R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54566219; called by muse, mutect2, varscan2
- IL22RA2 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | catalogued as COSV51664030; called by muse, mutect2, varscan2
- ITGB1BP2 | c.913C>G p.H305D | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52138949; called by muse, mutect2
- ITIH1 | c.1765C>A p.L589M | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV56256812; called by muse, mutect2, varscan2
- ITIH6 | c.993G>A p.W331* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as COSV54491402; called by muse, mutect2, varscan2
- ITIH6 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.035); catalogued as COSV54491417; called by muse, mutect2, varscan2
- KANSL1L | c.1349G>A p.C450Y | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV55994414; called by muse, mutect2
- KCND2 | c.507G>C p.Q169H | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV58592448; called by muse, mutect2, varscan2
- KCNV2 | c.1221C>A p.C407* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV66056922; called by muse, mutect2, varscan2
- KDM4B | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 59/454 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50236391; called by muse, mutect2, varscan2
- KNSTRN | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs768877625, COSV51107521; called by muse, mutect2, varscan2
- LAMB1 | c.2458+1G>A p.X820_splice | Splice Site (SNP) | VAF 14/116 reads (12%) | catalogued as COSV55967583; called by muse, mutect2
- LCE1B | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs754061206, COSV63980472; called by muse, mutect2, varscan2
- LEMD2 | c.719A>T p.Q240L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.264); catalogued as COSV53394618; called by muse, mutect2
- LHCGR | c.1929C>A p.C643* | Nonsense Mutation (SNP) | VAF 27/193 reads (14%) | catalogued as COSV54300283; called by muse, mutect2, varscan2
- LIN7A | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.689); catalogued as COSV54018296; called by muse, mutect2, varscan2
- LMAN2 | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57423916, COSV57425200; called by muse, mutect2, varscan2
- LRP10 | c.1477C>G p.P493A | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV62078600; called by muse, mutect2, varscan2
- LRP12 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52631546; called by muse, mutect2
- LRP1B | c.8966A>G p.Y2989C | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV67249362, COSV67263837; called by muse, mutect2, varscan2
- LRRC47 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as rs1557642343, COSV65563113; called by muse, mutect2
- MAGEB16 | c.570T>A p.Y190* | Nonsense Mutation (SNP) | VAF 9/106 reads (8%) | catalogued as COSV67874246; called by muse, mutect2
- MAGI1 | c.297C>G p.F99L | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58333985, COSV58335219; called by muse, mutect2, varscan2
- MALL | c.146A>G p.H49R | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV55601000; called by muse, mutect2, varscan2
- MDGA2 | c.2714G>C p.C905S (on ENST00000399232 / NM_001113498.2; = p.C607S on NM_182830.4) | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62103807; called by muse, mutect2, varscan2
- MMADHC | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57574167; called by muse, mutect2, varscan2
- MROH2B | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.64); catalogued as COSV68186910; called by muse, mutect2, varscan2
- MTMR8 | c.1460G>T p.S487I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV66395160; called by muse, mutect2
- MUC4 | c.13698G>C p.K4566N (on ENST00000463781 / NM_018406.7; = p.K330N on NM_004532.6) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV57791661; called by muse, mutect2, varscan2
- MYBL1 | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV72919109; called by muse, mutect2, varscan2
- MYH4 | c.3112-1G>T p.X1038_splice | Splice Site (SNP) | VAF 26/143 reads (18%) | catalogued as COSV55122485; called by muse, varscan2
- MYOM2 | c.2071G>C p.G691R | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50737282; called by muse, mutect2, varscan2
- NBEAL2 | c.5264G>A p.R1755H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs775767147, COSV52761032, COSV52761630; called by muse, mutect2, varscan2
- NGF | c.193G>C p.G65R | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.605); catalogued as COSV65688323; called by muse, mutect2, varscan2
- NLRC4 | c.328C>A p.H110N | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1426980819, COSV61593849; called by muse, mutect2, varscan2
- NOS3 | c.956+1G>T p.X319_splice | Splice Site (SNP) | VAF 89/367 reads (24%) | catalogued as COSV52492639; called by muse, mutect2, varscan2
- NPPB | c.288C>A p.Y96* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as COSV64687739; called by muse, mutect2, varscan2
- NRDE2 | c.1991A>G p.N664S | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV62963968; called by muse, mutect2
- NRXN3 | c.1589T>C p.V530A (on ENST00000335750 / NM_001330195.2; = p.V157A on NM_004796.6) | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV59777480; called by muse, mutect2
- NTM | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as COSV66186336; called by muse, mutect2, varscan2
- NTM | c.644T>G p.V215G | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66186359; called by muse, mutect2
- NWD1 | c.3653C>G p.T1218S | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV60346699; called by muse, mutect2, varscan2
- OPHN1 | c.2027G>A p.R676K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.122); catalogued as COSV62784554; called by muse, mutect2, varscan2
- OR11G2 | c.308A>T p.N103I | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62132762; called by muse, mutect2, varscan2
- OR1E1 | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.081); catalogued as COSV59459312; called by muse, mutect2, varscan2
- OR52N5 | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57699166; called by muse, mutect2, varscan2
- OR5H1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100641591, COSV63402924; called by muse, mutect2, varscan2
- OR5H14 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 60/359 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV71194262, COSV71194264; called by muse, mutect2, varscan2
- OR5I1 | c.911A>G p.E304G | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV56888134; called by muse, mutect2, varscan2
- OR6K2 | c.913C>A p.H305N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV62743877; called by muse, mutect2, varscan2
- OSBPL8 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV53886320; called by muse, mutect2, varscan2
- P2RX2 | c.963C>A p.Y321* (on ENST00000343948 / NM_170683.4; = p.Y249* on NM_012226.5) | Nonsense Mutation (SNP) | VAF 31/303 reads (10%) | catalogued as COSV57685562; called by muse, mutect2, varscan2
- PACS2 | c.2050G>T p.V684L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.186); catalogued as COSV57655527; called by muse, mutect2, varscan2
- PAPPA2 | c.1957C>A p.R653S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs370271956, COSV62778067; called by muse, mutect2, varscan2
- PCDH11X | c.1552C>A p.R518S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.932); catalogued as COSV53486709; called by muse, mutect2, varscan2
- PCDH11X | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53486739; called by muse, mutect2, varscan2
- PCDH15 | c.2909T>C p.V970A | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as COSV57352707; called by muse, mutect2, varscan2
- PCDHA7 | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs368032433, COSV65338759; called by muse, mutect2, varscan2
- PGRMC1 | c.572C>A p.A191D | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV54293194; called by muse, mutect2
- PKHD1 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61886768; called by muse, mutect2, varscan2
- PLEKHG4B | c.448G>A p.G150S (on ENST00000283426; = p.G506S on NM_052909.5) | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371569763; called by muse, mutect2, varscan2
- PLS3 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV56780629; called by muse, mutect2
- PNLIPRP1 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62612608; called by muse, mutect2, varscan2
- PPP1R3A | c.1721C>A p.T574N | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1471261440, COSV52887436; called by muse, mutect2, varscan2
- PPP4R3A | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.065); catalogued as COSV61505637; called by muse, mutect2, varscan2
- PPP4R4 | c.1365T>G p.D455E | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV58556409; called by muse, mutect2, varscan2
- PREX1 | c.4370G>A p.G1457D | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV64254284; called by muse, mutect2, varscan2
- PSG2 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 160/311 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV61545880; called by muse, mutect2, varscan2
- PTCHD1 | c.722A>T p.Q241L | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV65061819; called by muse, mutect2
- PTP4A3 | c.317C>A p.A106E | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61472319; called by muse, mutect2, varscan2
- PTPRN | c.2269A>G p.S757G | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV55350295; called by muse, mutect2
- PTPRN | c.1709G>C p.S570T | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV55350306; called by muse, mutect2
- RASA1 | c.2406G>A p.M802I | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57192907, COSV57198698; called by muse, mutect2, varscan2
- RCBTB1 | c.1349A>T p.Y450F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51635707; called by muse, mutect2, varscan2
- RELN | c.5332T>C p.C1778R | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59019480; called by muse, mutect2
- RFC4 | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as COSV56217365, COSV56217929; called by muse, mutect2, varscan2
- RINT1 | c.1357A>G p.M453V | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.42); catalogued as rs1184845991, COSV57559511; called by muse, mutect2, varscan2
- RYR2 | c.6834G>T p.Q2278H | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV63698992; called by muse, mutect2, varscan2
- RYR2 | c.9274C>A p.Q3092K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.701); catalogued as COSV63698999, COSV63709440; called by muse, mutect2, varscan2
- SAMD9 | c.1744A>G p.I582V | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1388047206, COSV66076704; called by muse, mutect2
- SATB2 | c.1210C>A p.P404T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53488960; called by muse, mutect2, varscan2
- SBF1 | c.1969-1G>T p.X657_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as COSV62369136; called by muse, mutect2
- SCN10A | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV71861609; called by muse, mutect2, varscan2
- SCN1A | c.5632G>T p.E1878* (on ENST00000303395 / NM_001202435.3; = p.E1867* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/104 reads (11%) | catalogued as rs148703212, COSV57667838; called by muse, mutect2, varscan2
- SCN3A | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); catalogued as COSV51809286; called by muse, mutect2, varscan2
- SDK2 | c.3394G>T p.V1132L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.475); catalogued as COSV66190552, COSV66191490, COSV66193653; called by muse, mutect2, varscan2
- SFTPA2 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 75/382 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs772763359, COSV64882452, COSV64882733; called by muse, mutect2, varscan2
- SIX4 | c.1010G>C p.G337A | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs745392790, COSV53670685; called by muse, mutect2, varscan2
- SLC4A4 | c.1174G>T p.E392* (on ENST00000264485 / NM_001098484.3; = p.E348* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV52630880; called by muse, mutect2
- SLTM | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs751738807, COSV51055760; called by muse, mutect2
- SMARCA4 | c.2080G>T p.D694Y | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV60802586, COSV60808993; called by muse, mutect2
- SMOX | c.980A>T p.H327L | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53866416; called by muse, mutect2, varscan2
- SNAI2 | c.128C>A p.P43Q | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV50079705; called by muse, mutect2, varscan2
- SPAM1 | c.893T>A p.L298H | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs766257029, COSV56145881; called by muse, mutect2, varscan2
- SPAST | c.1351A>G p.R451G | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as CD147727, COSV59515965; called by muse, mutect2, varscan2
- SPATA31E1 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.647); catalogued as COSV57793540; called by muse, mutect2, varscan2
- SPATA31E1 | c.3917G>T p.R1306M | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57793550; called by muse, mutect2, varscan2
- SPEG | c.2144G>T p.G715V | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56674945; called by muse, mutect2, varscan2
- STAT4 | c.2002G>C p.D668H | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61831160, COSV61832323; called by muse, mutect2, varscan2
- STRIP2 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV50806027; called by muse, mutect2, varscan2
- STYXL2 | c.2544G>T p.R848S | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54804362, COSV54807711; called by muse, mutect2, varscan2
- STYXL2 | c.2641G>T p.G881C | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs1206660067, COSV54807719; called by muse, mutect2, varscan2
- SYNCRIP | c.845A>C p.K282T | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV62288604; called by muse, mutect2, varscan2
- TBX18 | c.1372G>T p.V458L | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.282); catalogued as COSV63737497; called by muse, mutect2, varscan2
- TFEC | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); catalogued as rs896136629, COSV55403841; called by muse, mutect2
- TGM4 | c.549+1G>T p.X183_splice | Splice Site (SNP) | VAF 21/121 reads (17%) | catalogued as COSV56095184; called by muse, mutect2, varscan2
- TGM5 | c.1265C>A p.S422Y (on ENST00000220420 / NM_201631.4; = p.S340Y on NM_004245.4) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV55010889; called by muse, mutect2, varscan2
- TIGD4 | c.1168A>T p.T390S | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV58550224; called by muse, mutect2, varscan2
- TLN1 | c.3610C>T p.P1204S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318866452, COSV59209658; called by muse, mutect2, varscan2
- TMEM177 | c.935G>T p.*312Lext*74 | Nonstop Mutation (SNP) | VAF 17/114 reads (15%) | catalogued as COSV55609242; called by muse, mutect2, varscan2
- TNC | c.3250G>C p.E1084Q | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as COSV60787536, COSV60790096; called by muse, mutect2, varscan2
- TNN | c.821C>A p.T274K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53430657, COSV99511878; called by muse, mutect2
- TNR | c.3860T>A p.V1287E | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54900305; called by muse, mutect2
- TOX | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63844508, COSV63848528; called by muse, mutect2, varscan2
- TRAF6 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV61923091; called by muse, mutect2, varscan2
- TRAT1 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV55469702; called by muse, mutect2, varscan2
- TRIM50 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV60794596; called by muse, mutect2, varscan2
- TSHZ2 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs745999760, COSV61590076; called by muse, mutect2, varscan2
- TSHZ3 | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 24/472 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53676746; called by muse, mutect2
- TTN | c.98646C>G p.F32882L (on ENST00000591111; = p.F25458L on NM_003319.4) | Missense Mutation (SNP) | VAF 24/350 reads (7%) | PolyPhen benign (0.033); catalogued as COSV60196235; called by muse, mutect2
- TTN | c.15733C>T p.Q5245* (on ENST00000591111; = p.Q4318* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/160 reads (18%) | catalogued as COSV60196330; called by muse, mutect2, varscan2
- UBE3A | c.2507G>A p.R836K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV51668404; called by muse, mutect2, varscan2
- UBE3B | c.1056G>C p.K352N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV55095804; called by muse, mutect2, varscan2
- UGT2A3 | c.834G>T p.L278F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV52361179, COSV99279749; called by muse, mutect2, varscan2
- UGT2B4 | c.1314T>A p.Y438* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | catalogued as rs772218125; called by muse, mutect2
- UMPS | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 36/279 reads (13%) | catalogued as COSV51738139; called by muse, mutect2, varscan2
- USH2A | c.14232T>A p.H4744Q | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.462); catalogued as COSV56401308; called by muse, mutect2
- USP33 | c.2011A>G p.S671G | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.019); catalogued as rs1305626014, COSV62470420; called by muse, mutect2, varscan2
- UTRN | c.10270+1G>T p.X3424_splice | Splice Site (SNP) | VAF 11/97 reads (11%) | catalogued as COSV62310957; called by muse, mutect2, varscan2
- VSIG10 | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100821280; called by muse, mutect2, varscan2
- WDR17 | c.2677G>T p.V893F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV54578703; called by muse, mutect2, varscan2
- XXYLT1 | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV59986112; called by muse, mutect2
- ZBBX | c.952A>G p.M318V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs1344504797, COSV56795388; called by muse, mutect2, varscan2
- ZC4H2 | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.103); catalogued as COSV62005000; called by muse, mutect2, varscan2
- ZFPM2 | c.1690C>G p.L564V | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV65874769; called by muse, mutect2, varscan2
- ZFPM2 | c.2050C>A p.P684T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65874770; called by muse, mutect2, varscan2
- ZIM2 | c.929C>G p.T310S | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs762247047, COSV55640436; called by muse, mutect2, varscan2
- ZMYM6 | c.1955-1G>T p.X652_splice | Splice Site (SNP) | VAF 5/53 reads (9%) | catalogued as COSV64121772; called by muse, mutect2, varscan2
- ZNF112 | c.40G>A p.A14T (on ENST00000337401 / NM_001083335.2; = p.A8T on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61621237; called by muse, mutect2, varscan2
- ZNF208 | c.2849G>T p.C950F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68109833; called by muse, mutect2, varscan2
- ZNF222 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 15/280 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV51827625; called by muse, mutect2
- ZNF292 | c.1516G>T p.G506C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV60543046; called by muse, mutect2, varscan2
- ZNF383 | c.887A>T p.Q296L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.303); catalogued as COSV61939616; called by muse, mutect2, varscan2
- ZNF462 | c.4553G>T p.R1518M | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52946005; called by muse, mutect2, varscan2
- ZNF594 | c.1423C>G p.L475V | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV101280329, COSV68385834; called by muse, mutect2, varscan2
- ZNF704 | c.1118T>G p.V373G | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.04); catalogued as COSV59925822; called by muse, mutect2, varscan2
- ZNF804A | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100167703, COSV56448862; called by muse, mutect2, varscan2
- AMER3 | c.1789dup p.R597Kfs*14 | Frame Shift Ins (INS) | VAF 19/131 reads (15%) | called by mutect2, pindel, varscan2
- CALD1 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLC1 | c.4200del p.V1401* (on ENST00000276297 / NM_001348081.2; = p.V964* on NM_006094.5) | Frame Shift Del (DEL) | VAF 19/148 reads (13%) | called by mutect2, pindel, varscan2
- ELF2 | c.1460_1463del p.V487Efs*6 (on ENST00000379550 / NM_001331036.2; = p.V427Efs*6 on NM_006874.4) | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | called by mutect2, pindel, varscan2
- FBXO32 | c.347_360del p.S116Lfs*38 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- IGKV1D-17 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNT1 | c.2845C>A p.R949S (on ENST00000488444; = p.R968S on NM_020822.3) | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- LILRB4 | c.484C>A p.H162N | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- NF1 | c.5828_5838del p.H1943Rfs*17 (on ENST00000358273 / NM_001042492.3; = p.H1922Rfs*17 on NM_000267.3) | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | called by mutect2, pindel
- PAGE1 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- RBP3 | c.1352C>G p.S451C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RIN3 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- SLC16A14 | c.501del p.T168Pfs*7 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | called by pindel, varscan2
- TRGV4 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZCCHC12 | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ZNF254 | c.1235del p.G412Afs*15 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- ACSM2A | c.282C>T p.A94= (on ENST00000219054; = p.A15= on NM_001308169.2) | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV54587263; called by muse, mutect2, varscan2
- ADAM18 | c.15C>A p.L5= | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as COSV55851086; called by muse, mutect2
- ADAMTSL1 | c.48G>T p.L16= | Silent (SNP) | VAF 15/150 reads (10%) | catalogued as COSV52820036; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2727C>T p.I909= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs1487116800, COSV65895286; called by muse, mutect2, varscan2
- ANO2 | c.2322G>A p.V774= (on ENST00000356134 / NM_001278597.3; = p.V778= on NM_001278596.3) | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV59033382; called by muse, mutect2, varscan2
- ARF1 | c.453G>A p.R151= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs146827674; called by muse, mutect2, varscan2
- ARFGAP1 | c.105G>A p.V35= | Silent (SNP) | VAF 45/252 reads (18%) | catalogued as COSV62263537; called by muse, mutect2, varscan2
- ASCC2 | c.1470C>T p.C490= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV57075191; called by muse, mutect2, varscan2
- ATP10B | c.3195T>A p.A1065= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV59158769; called by muse, mutect2, varscan2
- BCHE | c.645A>G p.G215= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as COSV52259505; called by muse, mutect2, varscan2
- CAMKK2 | c.1140A>T p.L380= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV61216288; called by muse, mutect2, varscan2
- CCDC33 | c.408C>T p.P136= | Silent (SNP) | VAF 23/157 reads (15%) | catalogued as COSV100351744, COSV58354904; called by muse, mutect2, varscan2
- CHD7 | c.2133G>A p.K711= | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as COSV71112820; called by muse, mutect2
- CNTN6 | c.138C>A p.V46= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV63180842; called by muse, mutect2, varscan2
- CSMD3 | c.9082T>C p.L3028= (on ENST00000297405 / NM_001363185.1; = p.L2859= on NM_052900.3) | Silent (SNP) | VAF 30/165 reads (18%) | catalogued as COSV52248139; called by muse, mutect2, varscan2
- DSPP | c.1566T>C p.N522= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV56813326; called by muse, mutect2, varscan2
- EFEMP2 | c.327C>T p.C109= | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as COSV57260813; called by muse, mutect2, varscan2
- FLNC | c.3477G>T p.R1159= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV57960153; called by muse, mutect2, varscan2
- GABBR1 | c.2034C>T p.Y678= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs758589287, COSV63541979; called by muse, mutect2, varscan2
- HDC | c.741C>A p.T247= | Silent (SNP) | VAF 6/144 reads (4%) | catalogued as rs965590691, COSV51075051; called by muse, mutect2
- INO80D | c.999A>T p.P333= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV68959534; called by muse, mutect2, varscan2
- KPNA4 | c.1305A>G p.L435= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs145152566; called by muse, mutect2, varscan2
- LRIT2 | c.1494C>T p.R498= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs140185624; called by muse, mutect2, varscan2
- MAGEE1 | c.2520G>A p.Q840= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV63911195; called by muse, mutect2, varscan2
- MOCOS | c.1890G>A p.Q630= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as COSV54345366; called by muse, mutect2, varscan2
- MUC17 | c.5109C>A p.A1703= | Silent (SNP) | VAF 106/395 reads (27%) | catalogued as COSV60295996, COSV60300063; called by muse, mutect2, varscan2
- NRXN1 | c.3882G>C p.V1294= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as COSV60510448, COSV60520176; called by muse, mutect2, varscan2
- NTM | c.504T>C p.T168= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs932768205, COSV66186346, COSV66191564; called by muse, mutect2, varscan2
- NTRK1 | c.735A>G p.P245= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs771930428, COSV62327171; called by muse, mutect2, varscan2
- NUDT18 | c.825C>A p.T275= | Silent (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- NUP133 | c.621G>A p.K207= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV54573486; called by muse, mutect2
- NUP160 | c.1827C>T p.C609= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV65855108; called by muse, mutect2, varscan2
- OR1S2 | c.48A>G p.Q16= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs975870520, COSV100224217, COSV56919919; called by muse, mutect2, varscan2
- OR2L13 | c.261C>A p.G87= | Silent (SNP) | VAF 28/274 reads (10%) | catalogued as COSV63557127; called by muse, mutect2
- OR4Q3 | c.618G>T p.V206= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV59179530; called by muse, mutect2, varscan2
- OR51D1 | c.366C>A p.A122= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV62914935; called by muse, mutect2, varscan2
- OR52I1 | c.456C>T p.V152= | Silent (SNP) | VAF 40/131 reads (31%) | catalogued as COSV56169240; called by muse, mutect2, varscan2
- OR5M1 | c.438T>C p.T146= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV73202279; called by muse, mutect2, varscan2
- OR8B12 | c.46T>C p.L16= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as COSV60912285; called by muse, mutect2, varscan2
- ORC3 | c.99G>T p.G33= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV57642011; called by muse, mutect2, varscan2
- PAX4 | c.810C>T p.A270= | Silent (SNP) | VAF 60/214 reads (28%) | catalogued as COSV58389992; called by muse, mutect2, varscan2
- PNLIPRP1 | c.441G>T p.V147= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV62612601; called by muse, mutect2, varscan2
- PNPLA5 | c.954G>C p.L318= | Silent (SNP) | VAF 25/164 reads (15%) | catalogued as COSV53375561; called by muse, mutect2, varscan2
- PRDM1 | c.2235G>T p.V745= | Silent (SNP) | VAF 33/233 reads (14%) | catalogued as COSV64846016; called by muse, mutect2, varscan2
- PROS1 | c.1857G>T p.L619= | Silent (SNP) | VAF 23/145 reads (16%) | catalogued as COSV101260808; called by muse, varscan2
- PTPRJ | c.1335G>C p.P445= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV69253398; called by muse, mutect2, varscan2
- RGS5 | c.105C>T p.D35= | Silent (SNP) | VAF 31/184 reads (17%) | catalogued as COSV58353513; called by muse, mutect2, varscan2
- SAMD15 | c.924T>G p.T308= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as COSV53627091; called by muse, mutect2
- SCN11A | c.723C>G p.V241= | Silent (SNP) | VAF 6/135 reads (4%) | catalogued as COSV56574098; called by muse, mutect2
- SIRT5 | c.405C>T p.V135= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs760106683, COSV63081117; called by muse, mutect2, varscan2
- SLC6A18 | c.654G>T p.L218= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV57252918; called by muse, mutect2, varscan2
- SPTB | c.2508G>A p.Q836= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV67633565; called by muse, mutect2, varscan2
- SRPX | c.582C>G p.P194= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV59440088; called by muse, mutect2, varscan2
- STAB2 | c.1920C>G p.A640= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV66342903; called by muse, mutect2, varscan2
- TASP1 | c.879T>C p.C293= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as COSV61814353; called by muse, mutect2, varscan2
- TBC1D23 | c.1638T>A p.R546= (on ENST00000394144 / NM_001199198.3; = p.R531= on NM_018309.5) | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as COSV61369107; called by muse, varscan2
- TEKT3 | c.681G>T p.L227= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV58628623; called by muse, mutect2
- TMCC2 | c.1333C>T p.L445= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as COSV58005092; called by muse, mutect2, varscan2
- TMEM132D | c.2994G>A p.E998= | Silent (SNP) | VAF 28/157 reads (18%) | catalogued as COSV67161317; called by muse, mutect2, varscan2
- TRAT1 | c.288C>A p.A96= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV55469713; called by muse, mutect2, varscan2
- TRAV13-1 | c.111C>T p.S37= | Silent (SNP) | VAF 36/154 reads (23%) | catalogued as rs201830464; called by muse, mutect2, varscan2
- TRIM58 | c.492G>T p.V164= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- TTN | c.99306T>C p.Y33102= (on ENST00000591111; = p.Y25678= on NM_003319.4) | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs762295035, COSV60196194; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.94986A>G p.L31662= (on ENST00000591111; = p.L24238= on NM_003319.4) | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs878926568; called by mutect2, varscan2
- TTN | c.23937T>A p.S7979= (on ENST00000591111; = p.S7052= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV60196303; called by muse, mutect2, varscan2
- UNC93A | c.1308G>A p.P436= | Silent (SNP) | VAF 52/450 reads (12%) | catalogued as rs147514798; called by muse, varscan2
- ZHX2 | c.639A>G p.E213= | Silent (SNP) | VAF 35/192 reads (18%) | catalogued as COSV58715059; called by muse, mutect2, varscan2
- ZNF385D | c.120T>A p.P40= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV55765449; called by muse, mutect2, varscan2
- ZNF554 | c.321A>T p.S107= | Silent (SNP) | VAF 31/195 reads (16%) | catalogued as COSV57886405; called by muse, mutect2, varscan2
- AL590867.2 | n.114G>T | RNA (SNP) | VAF 29/245 reads (12%) | called by muse, mutect2, varscan2
- ARMC6 | c.*48G>C | 3'UTR (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99523022; called by muse, mutect2, varscan2
- C3P1 | n.2345C>A | RNA (SNP) | VAF 108/695 reads (16%) | called by muse, varscan2
- PNPLA3 | c.*360G>T | 3'UTR (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99337091; called by muse, mutect2, varscan2
- SNORD116-29 | n.5C>T | RNA (SNP) | VAF 14/64 reads (22%) | catalogued as rs974377887; called by muse, mutect2, varscan2
- SUGT1P4-STRA6LP | n.1337G>T | RNA (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
